Gene-level copy-number profile of tumor specimen ALCH-AFJT-TTP1-A from ALCHEMIST case ALCH-AFJT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.6 years (26,138 days).
Specimen ALCH-AFJT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 32bae770-fa2f-4d90-9fb4-9994a5bb538f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFJT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/b74dbd0e-2372-42e7-a43b-49a3b178ca52

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 5,954; copy number 2: 49,995; copy number 3: 2,053; copy number 4: 765; copy number 5: 23; copy number 6: 9; copy number 7: 18; copy number 11: 12; copy number 12: 7; copy number 13: 1; copy number 47: 2; copy number 53: 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr5:176,526,712–176,646,644, 8 genes: RNF44, CDHR2, RN7SL684P, Y_RNA, GPRIN1, SNCB, MIR4281, EIF4E1B.
- chr6:34,537,802–34,576,656, 2 genes: SPDEF, IFITM3P3.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr10:5,524,961–5,526,771, 2 genes (within-gene range 0–2): CALML3, AL732437.1.
- chr11:76,186,325–76,216,025, 3 genes: WNT11, AP000785.1, LINC02761.
- chr12:109,573,255–109,598,125, 1 gene (within-gene range 0–1): MVK.
- chr14:64,704,102–64,750,249, 1 gene (within-gene range 0–2): PLEKHG3.
- chr15:25,185,631–25,187,616, 2 genes (within-gene range 0–2): SNORD115-9, SNORD115-10.
- chr15:25,193,321–25,193,402, 1 gene (within-gene range 0–2): SNORD115-13.
- chr15:25,203,227–25,225,284, 13 genes (within-gene range 0–2): SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:710,746–711,277, 1 gene (within-gene range 0–2): Z97653.1.
- chr17:3,860,315–3,964,464, 3 genes: CAMKK1, P2RX1, ATP2A3.
- chr17:16,414,524–16,492,193, 9 genes: AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:27,746,132–27,800,529, 2 genes (within-gene range 0–2): LGALS9DP, NOS2.
- chr17:39,665,349–39,670,475, 2 genes: TCAP, PNMT.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:45,001,449–45,038,198, 1 gene: RELB.
- chr20:17,613,678–17,682,295, 1 gene: RRBP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 73 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 6: AC113430.1.
- chr7:54,752,250–55,646,951, 16 genes, copy number 7: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6.
- chr7:57,119,614–57,172,771, 8 genes, copy number 6–7: ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6.
- chr16:629,239–636,366, 2 genes, copy number 6 (within-gene range 2–6): WFIKKN1, METTL26.
- chr16:678,504–684,528, 4 genes, copy number 11 (within-gene range 2–11): LINC02867, Z92544.2, STUB1, JMJD8.
- chr22:18,400,407–18,577,968, 9 genes, copy number 12–47: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1.
- chr22:18,650,023–18,861,049, 8 genes, copy number 5–53: PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7.
- chr22:20,338,805–20,354,387, 3 genes, copy number 11 (within-gene range 2–11): FAM230G, AC007731.2, AC007731.5.
- chr22:21,103,016–21,396,590, 22 genes, copy number 5–13: BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5, LINC01651, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 3,098. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
